Somatic mutation profile of tumor specimen TCGA-3G-AB19-01A (aliquot TCGA-3G-AB19-01A-21D-A423-09) from TCGA case TCGA-3G-AB19, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 76.2 years (27,827 days).
Specimen TCGA-3G-AB19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc41751c-e3bf-48fc-af03-5ff57270f328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3G-AB19-11A (Solid Tissue Normal), aliquot TCGA-3G-AB19-11A-22D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55d90afb-5d60-4721-ab13-c19ca1914f27

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 10, Silent 8, Splice Site 2, Frame Shift Del 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 155/509 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs104894227, CM061796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ART5 | c.602_605del p.S201* | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs773024564; called by mutect2, pindel, varscan2
- HECW2 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99646685; called by muse, mutect2, varscan2
- VPS35L | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs570834372, COSV51990149; called by muse, mutect2, varscan2
- ADGRF3 | c.2719C>A p.P907T (on ENST00000311519 / NM_001145168.1; = p.P708T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- BDP1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EHMT2 | c.3111-1G>T p.X1037_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- KATNAL2 | c.289+1G>C p.X97_splice (on ENST00000356157 / NM_001353899.1; = p.X25_splice on NM_031303.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- MTHFD1 | c.2216_2224del p.K739_Q741del | In Frame Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- NRXN1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- PABPC5 | c.1137G>T p.R379S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SLC66A2 | c.172_174dup p.L58dup | In Frame Ins (INS) | VAF 11/25 reads (44%) | called by mutect2, varscan2
- TEAD4 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TM2D1 | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, varscan2
- ALAS2 | c.804C>A p.T268= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, varscan2
- ANLN | c.2328A>G p.E776= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- KIF3C | c.330C>G p.T110= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- NSUN2 | c.780C>A p.L260= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV52952987; called by muse, mutect2
- PPTC7 | c.282A>T p.S94= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- RIMS2 | c.2367A>G p.T789= (on ENST00000666250 / NM_001348490.2; = p.T597= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- SLC12A1 | c.2121C>T p.N707= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs766244569; called by muse, mutect2, varscan2
- ZNF789 | c.963C>G p.A321= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
